RC case RC-B54G — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e6144fa-a65a-4ed0-9b67-87ff9579be01

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1985; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Anaplastic large cell lymphoma, ALK negative: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 27.1 years (9,895 days); Year of diagnosis: 2012; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Iliac-Common / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Splenic / Lymph Node, Supraclavicular / Ascites / Peritoneum, NOS / Bone marrow / Gallbladder / Liver / Pleura / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.5 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CEOP; Days to treatment start: 7 days; Days to treatment end: 265 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pralatrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 7 days; Days to treatment end: 265 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Days to treatment start: 312 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, NOS.

Follow-up (5 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 3,080 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Day 3,702 (within 2 months after completion of first-course treatment): Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 3,702 days (10.1 years); Karnofsky performance status: 70; ECOG performance status: 2.
- Follow-up contact recording only the day: day 3,712.

Molecular and laboratory tests
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 1201 U/L [Blood test normal range upper: 192].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Initial Diagnosis; Weight: 63.5 kg; Height: 168 cm; BMI: 22.5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B54G-NM1-B: Tissue type: Normal; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
- Sample RC-B54G-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B54G-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 80; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
